Somatic mutation profile of tumor specimen 0DTC60 from CCDI case PBCJJB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Small cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 9.5 years (3,470 days).
Specimen 0DTC60: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4381bbba-b15c-4568-8f00-bdd0760cff0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTC5U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99c18e23-b78c-4c38-ad00-c24b3f0a7ac7

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRQ | c.6574C>T p.R2192* (on ENST00000616559; = p.R2159* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 47/1050 reads (4%) | catalogued as rs1445287184, CM136600, COSV57037727; ClinVar: pathogenic; called by muse, mutect2
- APBA1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 194/433 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV55228883; called by muse, mutect2, varscan2
- FBN3 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 159/376 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1480343659; called by muse, mutect2, varscan2
- GATA4 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 16/497 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58732542; called by muse, mutect2
- NEIL2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 270/696 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as rs751408660; called by muse, mutect2, varscan2
- RAD54L2 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 220/580 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99621602; called by muse, mutect2, varscan2
- SIX4 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as rs764503585, COSV99382190; called by mutect2, varscan2
- SSRP1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 290/782 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV53480567; called by muse, mutect2, varscan2
- TTN | c.22975G>A p.V7659I (on ENST00000591111; = p.V6732I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/651 reads (36%) | PolyPhen possibly damaging (0.502); catalogued as rs200395305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP22 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 433/1083 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs373343514; called by muse, mutect2, varscan2
- WDR75 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 341/978 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1166378635; called by muse, mutect2, varscan2
- CADPS2 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 338/890 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- FAM110B | c.1075A>C p.K359Q | Missense Mutation (SNP) | VAF 269/769 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- SIX4 | c.153T>A p.F51L | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 34/932 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ARHGAP15 | c.630C>T p.S210= | Silent (SNP) | VAF 368/1030 reads (36%) | called by muse, mutect2
- FGD5 | c.288G>A p.A96= | Silent (SNP) | VAF 292/788 reads (37%) | catalogued as rs1559466192, COSV53243868; called by muse, mutect2, varscan2
- PCDH11X | c.3381T>A p.T1127= | Silent (SNP) | VAF 155/408 reads (38%) | called by muse, mutect2, varscan2
- ZNF652 | c.1437C>T p.R479= | Silent (SNP) | VAF 351/739 reads (47%) | called by muse, mutect2, varscan2
- AMDHD2 | c.*923C>T | 3'UTR (SNP) | VAF 107/292 reads (37%) | catalogued as rs766056159; called by muse, mutect2, varscan2
- PNP | c.285+87G>T | Intron (SNP) | VAF 55/125 reads (44%) | called by muse, mutect2, varscan2
- SPTAN1 | c.4758+40T>C | Intron (SNP) | VAF 89/237 reads (38%) | called by muse, mutect2, varscan2
